Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RK, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RK-02B (Recurrent Tumor).

ICD-0-3
Oligoastrocytoma, grade II 9382/3
Site: ^{case}Supratentorial brain NOS C71.2
^{path}Brain, frontal lobe C71.1
QW 1/29/14

Nature of material: Brain
Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received two irregular, whitish and soft fragments, measuring 1.0 x 0.6 x 0.4 cm.

MICROSCOPY

The histological sections stained with H & E show fragments of glial neoplasia, mainly located in the white matter, showing double cell population. The neoplastic cells exhibit sometimes round nuclei, delicate chromatin and inconspicuous nucleoli with scant cytoplasm, and sometimes convoluted and irregular nuclei, with dense chromatin and eosinophilic cytoplasm, with imprecise limits. The tumor shows looser areas where occasional microcysts are seen, filled with amorphous and basophilic material. Mitotic figures are rare (about 1 mitosis for 10-20 high-power fields). However, in some areas, the tumor exhibits greater cellularity and cellular atypia. Are not observed vessels with microvascular proliferation and / or necrotic areas in this material.

PER-OPERATIVE

Cytological findings suggestive of high-grade glioma.

DIAGNOSTIC

Product of excisional biopsy of a tumor relapse in left frontal lobe:

-Oligoastrocitoma with focal atypia (WHO grade II) in this material.

COMMENTS:

-To material sent below see report

NOTES:

-Patient operated in _____ and _____ for grade II oligoastrocitoma in
left frontal lobe - see reports _____ and _____ respectively.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Recurrence 2 of 2 of primary
Grade II LGG *hu*

Source: NCI Genomic Data Commons file 9d64a834-1832-41c3-aedd-fd36c9458fc7 (TCGA-TQ-A7RK.5452FDC5-EB15-49DE-A0CC-9A9CA7018A5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).